Somatic mutation profile of tumor specimen BA2692D (aliquot aq-BA2692D) from BEATAML1.0 case 2068, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.6 years (21,416 days).
Specimen BA2692D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8921fe5-3d6a-4b0e-9810-0d6d636bdb1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2298D (Solid Tissue Normal), aliquot aq-BA2298D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00f3c1b6-ee6f-4e03-8212-73ddc7c9c55b

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF1AX | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV63309390, COSV63309515; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 28/348 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CROCC2 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1340383156; called by muse, mutect2, varscan2
- RBMS2 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, varscan2
- CHAT | c.786G>A p.Q262= | Silent (SNP) | VAF 55/222 reads (25%) | called by muse, mutect2, varscan2
- SLC2A1 | c.516+122A>G | Intron (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2
- TMEM135 | c.*4183C>G | 3'UTR (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
